Surgical pathology report (de-identified scan), TCGA case TCGA-55-6979, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-6979-01A (Primary Tumor).

[page 1 of 3]
Site Controls:

<Select>

Patient:

**CM Transcription**[Back to List](#)

TEST: Surgical Pathology

Date & Time

REPORT STATUS: Final

FACILITY:

Patient:

Surgical Pathology SURGICAL P
SURGICAL PATHOLOGY REPORT

Patient Name:

Accession #

Med. Rec. #:

Billing Type:

Location:

DOB:

Service: Surgery

Gender: F

Billing #

Taken

Received

Reported:

Physician(s):

Specimen(s) Received

- A: Lung wedge left lower lobe
- B: Lymph node level 2
- C: Lung left upper lobe
- D: Level 6 lymph node
- E: Level 9 lymph node

Pathologic Diagnosis

- A. Lung wedge left lower lobe: Old calcified granuloma.
- B. Lymph node level 2: One benign lymph node.

C. Lung left upper lobe:

Histologic Type: Adenocarcinoma
Histologic Grade: Poorly differentiated
Tumor Size: Greatest dimension: 4.1 cm
Additional dimension: 3 cm
Specimen Type: Lobectomy
Extent of Invasion: Tumor is confined to the lung
Regional Lymph Nodes: Number involved: 1
Distant Metastasis: Cannot be assessed
Margins: Margins uninvolved by invasive carcinoma
Lymphovascular Invasion: Present

[page 2 of 3]
Venous Invasion: Absent
Arterial Invasion: Absent

D. Level 6 lymph node: Two benign lymph nodes.

E. Level 9 lymph node: One benign lymph node.

Comment: There is a total of one of six lymph nodes positive for metastatic carcinoma. The positive node was adjacent to the bronchus in the lobectomy specimen. One additional benign lymph node was present in this location.

PATHOLOGIC STAGE: pT2, pN1, pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated and does not incorporate other relevant data. Pathology stage is only a component to be considered in determining the clinical stage and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Primary Pathologist: [REDACTED]

[REDACTED] Electronically Signed Out By: [REDACTED]

Clinical History

Left lung mass.

Intraoperative Consultation

A - Wedge of left lower lobe: Calcified nodule, grossly benign.

C - Left upper lobe lobectomy: Bronchial margins clear.

Donna G. Horne, M.D.

Gross Description

The specimen is received in multiple parts with the first received fresh. This consists of a wedge of lung which measures approximately 3 cm in maximum dimension. Basal margins are present. The specimen is sectioned to show a 6 cm calcified yellow-white nodule. The specimen is submitted totally after decalcification.

The specimen received as level 2, is received in formalin and is designated specimen "B". This consists of a single piece of gray-black tissue measuring 3 mm in greatest dimension, totally submitted.

The specimen received as left upper lobe is designated specimen "C", and is received fresh. This consists of a lobe of lung which weighs 138 gm and measures 14 x 9 x 4.5 cm. The surface shows marked puckering of the pleura and this area is inked prior to sectioning. The bronchial margins are removed for frozen section. Sectioning the lung shows a firm lobulated gray-white tumor which is subpleural in location, although grossly does not appear to extend through the pleura. The tumor measures 4.1 x 2.3 x 3 cm. It is located beneath the pleura and approximately 1 cm from the bronchial resection margin. The lung parenchyma is not involved by tumor, it is pink and soft. Sectioning the peribronchial tissue shows a large lymph node measuring 1.3 cm in greatest dimension. This is inked with blue dye and sectioned into three parts. A possible additional node is identified. It

[page 3 of 3]
is placed in cassette 7. Sections have been submitted as follows: "C1", bronchial resection margin; "C2-5", tumor with pleural margin inked; "C6", random sections and "C7", bronchial node.

The specimen received as "level 6 lymph node" is designated specimen "D", and this consists of two lymph nodes with the larger one measuring 2 cm in maximum dimension. This is bisected and placed in cassette 1. The other node measures 1 cm in greatest dimension, and this is bisected and placed in cassette 2. An additional 4 mm node is added in cassette "D1". The specimen received as "level 9 lymph node" is designated specimen "E", and this consists of a red-gray lymph node which measures 1 cm in greatest dimension. This is bisected and totally submitted.

Microscopic Description

Microscopic examination has been performed on all slides. The pathologic diagnosis encompasses the essential microscopic findings of this case.

Source: NCI Genomic Data Commons file 503b2966-6c39-4526-9f3b-2bb90c2dbf69 (TCGA-55-6979.C7896F40-C1A5-4E4C-BFEA-7E80C94C66AD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).